Somatic mutation profile of tumor specimen TCGA-DJ-A3VG-01A (aliquot TCGA-DJ-A3VG-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VG, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.0 years (14,970 days).
Specimen TCGA-DJ-A3VG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4409dbf3-e4de-4bcb-909c-74b0eb909905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VG-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VG-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27871dac-650a-4f79-b363-561b2c0cba93

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 72/161 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATXN7L1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100596762; called by muse, mutect2, varscan2
- CASP14 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as rs546136139, COSV55666280; called by muse, mutect2, varscan2
- CSNK2A1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs1177251051, COSV99424234; called by muse, mutect2, varscan2
- ENTPD7 | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100978354; called by muse, mutect2
- GSTO2 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354178565, COSV100086611; called by muse, mutect2, varscan2
- LAMA4 | c.2430C>A p.N810K (on ENST00000230538 / NM_001105206.3; = p.N803K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100037726, COSV57891338; called by muse, mutect2, varscan2
- OR8H2 | c.47T>A p.M16K | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV100542168, COSV57945217; called by muse, mutect2, varscan2
- PCDH19 | c.2511C>G p.N837K (on ENST00000373034 / NM_001184880.2; = p.N790K on NM_020766.3) | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV99719148; called by muse, mutect2, varscan2
- SLC41A1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371237657, COSV65650939; called by muse, mutect2, varscan2
- TARS1 | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99465546; called by muse, mutect2, varscan2
- TONSL | c.1520A>T p.D507V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as COSV101340154; called by muse, mutect2, varscan2
- ZC3H12A | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1210263301, COSV100897653; called by muse, mutect2, varscan2
- AIFM3 | c.106del p.S36Afs*61 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- GTF2H1 | c.51A>G p.Q17= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1220398073, COSV99786343; called by muse, mutect2
- OTOL1 | c.423C>A p.P141= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100019790; called by muse, mutect2
- TGM6 | c.336C>T p.Y112= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV99171695; called by muse, mutect2, varscan2
